Somatic mutation profile of tumor specimen TCGA-13-0889-01A (aliquot TCGA-13-0889-01A-01W-0420-08) from TCGA case TCGA-13-0889, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: GX; Age at diagnosis: 75.8 years (27,674 days).
Specimen TCGA-13-0889-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdb89aa0-0d51-4312-96a8-cd4d57b05b35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0889-10A (Blood Derived Normal), aliquot TCGA-13-0889-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ee1e9d3-6166-4947-a90c-c0d40f7321f8

The open-access MAF lists 170 somatic variants for this specimen: 170 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 162, Missense Mutation 5, Splice Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 87/119 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.181_182insC p.C61Sfs*12 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | catalogued as COSV99868358; called by mutect2, pindel
- DGKD | c.1573_1574insG p.T525Sfs*32 (on ENST00000264057 / NM_152879.3; = p.T481Sfs*32 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | catalogued as COSV99897889; called by mutect2, pindel
- LRP1 | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54528981; called by mutect2, varscan2
- MAPK14 | c.833A>T p.N278I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57698094; called by mutect2, varscan2
- NONO | c.905_906insG p.A303Cfs*4 | Frame Shift Ins (INS) | VAF 10/119 reads (8%) | catalogued as COSV99339224; called by mutect2, pindel
- PPP2R5B | c.1116+1G>T p.X372_splice | Splice Site (SNP) | VAF 25/76 reads (33%) | catalogued as COSV51214150; called by muse, mutect2, varscan2
- PRKCE | c.475dup p.A159Gfs*116 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | catalogued as rs869061504; called by mutect2, pindel
- TCF12 | c.747dup p.G250Wfs*16 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | catalogued as COSV99979201; called by mutect2, pindel
- AAK1 | c.995dup p.L333Afs*3 | Frame Shift Ins (INS) | VAF 6/61 reads (10%) | called by mutect2, pindel*
- ABL1 | c.3189_3190insG p.Y1064Vfs*30 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ACSL6 | c.1014dup p.G339Rfs*16 (on ENST00000379240; = p.G364Rfs*16 on NM_015256.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by mutect2, pindel
- AGAP2 | c.1994_1995insA p.S665Rfs*41 (on ENST00000547588 / NM_001122772.2; = p.S329Rfs*41 on NM_014770.4) | Frame Shift Ins (INS) | VAF 6/77 reads (8%) | called by mutect2, pindel
- AGK | c.514_515insA p.V172Dfs*6 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- AKAP9 | c.5778dup p.C1927Vfs*11 (on ENST00000359028; = p.C1895Vfs*11 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- ALPK2 | c.5791dup p.R1931Pfs*25 | Frame Shift Ins (INS) | VAF 6/72 reads (8%) | called by mutect2, pindel
- APAF1 | c.1519_1520insG p.L507Rfs*5 (on ENST00000551964 / NM_181861.2; = p.L496Rfs*5 on NM_001160.3) | Frame Shift Ins (INS) | VAF 8/73 reads (11%) | called by mutect2, pindel*
- BCL11A | c.111_112insC p.A38Rfs*7 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | called by mutect2, pindel*
- BIRC2 | c.269dup p.D91Gfs*2 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- BRAF | c.1014_1015insC p.S339Lfs*13 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by mutect2, pindel
- BRCA2 | c.2761_2762insC p.I921Tfs*15 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- BRD8 | c.3099_3100insG p.L1034Afs*6 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- CAMKK1 | c.891dup p.N298Qfs*4 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- CAMKK2 | c.1012_1013insC p.K338Tfs*4 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CCL4 | c.44_45insG p.A16Cfs*38 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- CDK3 | c.179_180insG p.H60Qfs*22 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- CDKL5 | c.797dup p.L266Ffs*3 | Frame Shift Ins (INS) | VAF 7/68 reads (10%) | called by mutect2, pindel
- CHD9 | c.4542_4543insG p.S1515Vfs*11 | Frame Shift Ins (INS) | VAF 6/71 reads (8%) | called by mutect2, pindel*
- CIT | c.2794dup p.I932Nfs*6 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, pindel
- CLK3 | c.942dup p.F315Lfs*58 (on ENST00000395066 / NM_001130028.1; = p.F167Lfs*58 on NM_003992.4) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CLTCL1 | c.2227dup p.E743Gfs*37 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- CREBBP | c.3642dup p.G1215Wfs*19 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CSF3R | c.2020_2021insC p.V674Afs*30 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- CSMD3 | c.160_161insG p.T54Sfs*20 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CSNK1A1 | c.182_183insA p.S61Rfs*5 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- CSNK1D | c.364_365insG p.K122Rfs*48 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | called by mutect2, pindel*
- CYP24A1 | c.874_875insC p.K292Tfs*7 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel
- DDB2 | c.214dup p.T72Nfs*6 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel
- DDX6 | c.702_703insC p.A235Rfs*4 | Frame Shift Ins (INS) | VAF 6/71 reads (8%) | called by mutect2, pindel*
- DGKD | c.2892_2893insC p.S965Lfs*80 (on ENST00000264057 / NM_152879.3; = p.S921Lfs*80 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/54 reads (7%) | called by mutect2, pindel
- DGKK | c.2075dup p.I693Dfs*16 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel
- DNM1L | c.799_800insT p.A267Vfs*13 | Frame Shift Ins (INS) | VAF 5/62 reads (8%) | called by mutect2, pindel*
- DOLK | c.224dup p.M75Ifs*34 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- DUSP7 | c.841dup p.L281Pfs*20 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- EEF2K | c.1556_1557insT p.K520Efs*80 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- EFNB3 | c.167_168insG p.D56Efs*20 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- EGF | c.2413_2414insC p.I805Tfs*6 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- EPHA4 | c.159+1dup p.X53_splice | Splice Site (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel
- EPHA7 | c.2770_2771insT p.T924Ifs*13 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- EPHA8 | c.250dup p.L84Pfs*17 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- EPHB2 | c.1269dup p.F424Vfs*47 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- EPS15 | c.169dup p.W57Lfs*37 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ESR2 | c.1291_1292insG p.N431Rfs*27 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ETNK1 | c.625dup p.S209Ffs*12 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- EWSR1 | c.308_309insA p.T104Yfs*44 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- EXT2 | c.998_999insG p.D333Efs*22 (on ENST00000343631; = p.D366Efs*22 on NM_000401.3) | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | called by mutect2, pindel
- EZH2 | c.1889_1890insG p.D630Efs*7 (on ENST00000460911 / NM_001203247.2; = p.D635Efs*7 on NM_004456.5) | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- FANCC | c.931_932insC p.I311Tfs*63 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- FANCC | c.518_519insC p.R173Sfs*25 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- FANCC | c.73dup p.A25Gfs*26 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by mutect2, pindel
- FANCD2 | c.796dup p.V266Gfs*4 | Frame Shift Ins (INS) | VAF 5/56 reads (9%) | called by mutect2, pindel
- FBXO10 | c.2821dup p.V941Gfs*72 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- FBXO24 | c.366_367insG p.C123Vfs*28 (on ENST00000241071 / NM_033506.3; = p.C161Vfs*28 on NM_012172.5) | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- FLT1 | c.3234dup p.K1079Qfs*29 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- GLI1 | c.2160_2161insA p.Y721Ifs*8 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel
- GLI1 | c.2995dup p.Y999Lfs*17 | Frame Shift Ins (INS) | VAF 6/59 reads (10%) | called by mutect2, pindel
- GRB2 | c.473dup p.T159Dfs*8 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- GSK3B | c.394_395insG p.L132Rfs*16 | Frame Shift Ins (INS) | VAF 5/77 reads (6%) | called by mutect2, pindel*
- HAT1 | c.900_901insC p.S301Lfs*11 | Frame Shift Ins (INS) | VAF 6/79 reads (8%) | called by mutect2, pindel
- HDAC3 | c.80_81insC p.R28Sfs*7 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- HEPH | c.1423dup p.R475Pfs*16 (on ENST00000343002; = p.R208Pfs*16 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- HERC2 | c.4960dup p.M1654Nfs*49 | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | called by mutect2, pindel
- HTT | c.7315_7316insC p.F2439Sfs*9 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- HUWE1 | c.11500dup p.E3834Gfs*10 | Frame Shift Ins (INS) | VAF 6/59 reads (10%) | called by mutect2, pindel
- HUWE1 | c.8384dup p.S2796Qfs*45 | Frame Shift Ins (INS) | VAF 10/92 reads (11%) | called by mutect2, pindel
- HUWE1 | c.4567dup p.A1523Gfs*7 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel
- HUWE1 | c.1183_1184insC p.S395Tfs*7 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel
- HUWE1 | c.424_425insT p.S142Mfs*13 | Frame Shift Ins (INS) | VAF 4/50 reads (8%) | called by mutect2, pindel
- IFNA14 | c.437_438insT p.F147Lfs*52 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- IGF2R | c.982dup p.C328Lfs*43 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- IGF2R | c.6199dup p.V2067Gfs*4 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- ITGA5 | c.2125dup p.H709Pfs*11 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ITGA5 | c.1660_1661insG p.K554Rfs*101 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- ITPK1 | c.610_611insA p.G204Efs*23 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- ITPR2 | c.2245dup p.I749Nfs*20 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by mutect2, pindel
- JAK2 | c.386dup p.N129Kfs*13 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- JAK2 | c.1832dup p.L611Ffs*32 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel
- JAKMIP1 | c.1090_1091insC p.N364Tfs*22 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel*
- KALRN | c.5247dup p.S1750Lfs*19 (on ENST00000360013 / NM_001024660.4; = p.S53Lfs*19 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- KDR | c.1429_1430insG p.T477Sfs*7 | Frame Shift Ins (INS) | VAF 3/43 reads (7%) | called by mutect2, pindel
- KMT2A | c.9635_9636insA p.T3213Hfs*20 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- KMT2D | c.15755_15756insG p.D5252Efs*6 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- LRP1B | c.9863_9864insT p.L3289Pfs*15 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- LRP6 | c.2321_2322insG p.D774Efs*9 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by mutect2, pindel
- LRRK1 | c.1309dup p.L437Pfs*37 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- MAGI2 | c.1006dup p.A336Gfs*5 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- MAP3K4 | c.4596dup p.C1533Vfs*15 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- MAPKBP1 | c.2687_2688insC p.P897Sfs*10 (on ENST00000456763 / NM_001128608.2; = p.P891Sfs*10 on NM_014994.3) | Frame Shift Ins (INS) | VAF 3/37 reads (8%) | called by mutect2, pindel
- MAST4 | c.1992dup p.L665Sfs*4 (on ENST00000403625 / NM_001164664.2; = p.L476Sfs*4 on NM_015183.3) | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | called by mutect2, pindel
- MDC1 | c.4902_4903insC p.S1635Lfs*2 | Frame Shift Ins (INS) | VAF 4/52 reads (8%) | called by mutect2, pindel
- MLLT3 | c.785_786insC p.E262Dfs*6 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- MYO3A | c.2489_2490insG p.H830Qfs*10 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel
- MYO3B | c.2581dup p.V861Gfs*25 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel
- NCK1 | c.832_833insT p.A278Vfs*21 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- NCOA3 | c.507dup p.L170Sfs*2 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel
- NF1 | c.2675_2676insA p.S892Rfs*14 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel
- NF1 | c.8473dup p.R2825Kfs*9 (on ENST00000358273 / NM_001042492.3; = p.R2804Kfs*9 on NM_000267.3) | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, pindel
- NFKBIA | c.896dup p.E300Rfs*7 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- NIN | c.2787_2788insT p.Q930Sfs*6 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel
- NLK | c.1213dup p.C405Lfs*7 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- NSD3 | c.3664_3665insG p.M1222Sfs*6 | Frame Shift Ins (INS) | VAF 3/39 reads (8%) | called by mutect2, pindel
- NSD3 | c.3249_3250insG p.K1084Efs*8 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- NUCKS1 | c.652_653insG p.K218Rfs*15 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- OPA1 | c.2083_2084insT p.A695Vfs*11 (on ENST00000361510 / NM_130837.3; = p.A640Vfs*11 on NM_015560.3) | Frame Shift Ins (INS) | VAF 7/70 reads (10%) | called by mutect2, pindel
- PAK2 | c.597dup p.D200* | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel
- PAK5 | c.1001_1002insC p.R335Sfs*14 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- PARP1 | c.2177dup p.D726Efs*41 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- PASK | c.382dup p.C128Lfs*4 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, pindel
- PHIP | c.1617_1618insT p.I540Yfs*8 | Frame Shift Ins (INS) | VAF 4/49 reads (8%) | called by mutect2, pindel
- PIK3CB | c.1338dup p.D447* | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- PIK3R1 | c.593_594insC p.P199Sfs*7 | Frame Shift Ins (INS) | VAF 3/36 reads (8%) | called by mutect2, pindel
- PLK3 | c.1011dup p.N338Qfs*4 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | called by mutect2, pindel
- PPARA | c.707_708insC p.P237Sfs*7 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | called by mutect2, pindel
- PPEF2 | c.1680dup p.A561Sfs*16 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel
- PPFIA2 | c.3007dup p.S1003Kfs*20 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel
- PPP1R2 | c.403+1dup p.X135_splice | Splice Site (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- PPP3CA | c.317dup p.S107Ifs*15 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, pindel
- PPP3CC | c.907dup p.S303Ffs*10 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by mutect2, pindel
- PRKCA | c.1664_1665insG p.S556Ffs*31 | Frame Shift Ins (INS) | VAF 9/94 reads (10%) | called by mutect2, pindel
- PRKG1 | c.1868_1869insG p.N623Kfs*13 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by mutect2, pindel
- PRKRA | c.452dup p.G152Rfs*5 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel
- PRMT7 | c.788_789insC p.S264* | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- PTK2 | c.2558dup p.P854Sfs*13 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- PTPN13 | c.3383dup p.G1129Wfs*5 (on ENST00000411767 / NM_080683.3; = p.G1110Wfs*5 on NM_006264.3) | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, pindel
- PTPN18 | c.748dup p.L250Pfs*8 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- PTPN21 | c.55dup p.S19Kfs*13 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PTPN22 | c.407dup p.K137Efs*4 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel
- PTPRK | c.2239_2240insG p.T747Sfs*11 (on ENST00000368215 / NM_001291984.2; = p.T748Sfs*11 on NM_002844.4) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- RAB2A | c.245_246insG p.L83Ffs*38 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- RABEP1 | c.70dup p.I24Nfs*2 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- RAD51B | c.374_375insA p.T126Yfs*17 | Frame Shift Ins (INS) | VAF 12/146 reads (8%) | called by mutect2, pindel
- RB1 | c.1053dup p.E352* | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- RHOC | c.269_270insG p.D90Efs*8 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- RPS6KA3 | c.2082_2083insC p.A695Rfs*19 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- SACS | c.13481dup p.S4496Vfs*2 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, pindel
- SETD2 | c.5129_5130insC p.K1711* | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- SIK3 | c.385_386insG p.R130Afs*11 (on ENST00000445177 / NM_001366686.2; = p.R136Afs*11 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel
- SIK3 | c.319dup p.V108Sfs*33 (on ENST00000445177 / NM_001366686.2; = p.V114Sfs*33 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- SKAP1 | c.923_924insG p.D308Efs*5 | Frame Shift Ins (INS) | VAF 8/108 reads (7%) | called by mutect2, pindel
- SNRK | c.2230_2231insC p.I744Tfs*6 | Frame Shift Ins (INS) | VAF 5/57 reads (9%) | called by mutect2, pindel
- STK3 | c.296dup p.M99Ifs*14 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- SUFU | c.676dup p.V226Gfs*12 | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- TAF15 | c.304_305insA p.A102Dfs*5 (on ENST00000605844 / NM_139215.3; = p.A99Dfs*5 on NM_003487.4) | Frame Shift Ins (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
- TEX14 | c.3440_3441insC p.Q1147Hfs*9 (on ENST00000240361 / NM_001201457.2; = p.Q1101Hfs*9 on NM_031272.5) | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by mutect2, pindel
- TNKS2 | c.2672dup p.M891Ifs*5 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by mutect2, pindel
- TOP2A | c.3346_3347insC p.D1116Afs*15 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- TPR | c.3675_3676insG p.Q1226Afs*4 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | called by mutect2, pindel
- TRAF2 | c.281_282insG p.N94Kfs*17 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- TRIP11 | c.3228_3229insC p.S1077Lfs*31 | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, pindel
- TRIP12 | c.3462_3463insC p.S1155Lfs*3 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- TRIP12 | c.3027dup p.P1010Afs*12 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- TRPM7 | c.1872_1873insT p.L625Sfs*22 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- TSSK1B | c.394_395insC p.V132Afs*9 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel
- TTN | c.44880_44881insA p.A14961Sfs*25 (on ENST00000591111; = p.A7537Sfs*25 on NM_003319.4) | Frame Shift Ins (INS) | VAF 6/78 reads (8%) | called by mutect2, pindel*
- TYK2 | c.3445_3446insG p.K1149Rfs*26 | Frame Shift Ins (INS) | VAF 4/47 reads (9%) | called by mutect2, pindel
- UBR5 | c.1154dup p.S385Rfs*3 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by mutect2, pindel
- UHRF2 | c.273dup p.C92Lfs*3 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, pindel
- WAS | c.945_946insT p.P316Sfs*20 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel
